Gene-level copy-number profile of tumor specimen TCGA-O2-A52S-01A from TCGA case TCGA-O2-A52S, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage III; Age at diagnosis: 58.0 years (21,182 days).
Specimen TCGA-O2-A52S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8df92f22-689b-440d-b492-453a2cb64ee2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-O2-A52S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/145cbb93-f672-4604-8d0e-875309a9f6a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 23,820; copy number 2: 28,243; copy number 3: 5,953; copy number 4: 1,530; copy number 5: 173; copy number 6: 2; copy number 7: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-O2-A52S-01A-11D-A25M-01): tumor purity 0.75, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,231,423–142,131,016, 1 gene (within-gene range 0–2): LRP1B.
- chr2:140,586,626–141,208,376, 6 genes: MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr8:16,863,196–17,002,345, 2 genes: RN7SL474P, FGF20.
- chr15:52,755,053–53,129,698, 5 genes: ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490.
- chr18:71,137,829–71,208,366, 1 gene: AC091691.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 252 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:103,100,143–103,927,806, 14 genes, copy number 5: SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1.
- chr6:82,353,861–82,367,420, 2 genes, copy number 6: AL121977.2, TPBG.
- chr9:27,245,680–28,888,955, 17 genes, copy number 5 (within-gene range 1–5): LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr11:68,312,591–71,549,608, 77 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:37,084,992–40,565,472, 142 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,433. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
